Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6954, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6954-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (G) RIGHT TONGUE AND MANDIBLE, RESECTION:
MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING MANDIBLE
BONE AND EXTENDING BEYOND GINGIVAL-BUCCAL SULCUS TO THE
SUBCUTANEOUS TISSUE AND DEEP DERMIS OF THE OVERLYING SKIN OF
THE SKIN.

Resection margin free of tumor.

GROSS DESCRIPTION:

SECTION CODE: Gad1, skin and tumor; Gad2, Gad3, anterior mandibular
margin; Gad4, Gad5, tumor in mandible; Gad6, Gad7, posterior mandibular
margin.

Entire report and diagnosis completed by
Report released by

SIGNATURE:

ENTIRE REPORT ELECTRONICALLY SIGNED BY:

DIAGNOSIS

- (A) SKIN FLAP, RIGHT CHEEK:
Skin, no diagnostic abnormality.
- (B) LEFT SUBMANDIBULAR LYMPH NODES:
Two lymph nodes, no evidence of metastatic disease.
- (C) RIGHT NECK DISSECTION:
Twenty-two lymph nodes, no evidence of metastatic disease (8 LEVEL I,
5 LEVEL II AND 9 LEVEL IV).
Chronic sialadenitis, submandibular gland.
- (D) MASSETER MARGIN:
Skeletal muscle, no evidence of carcinoma.
- (E) POSTERIOR BUCCAL MARGIN:
Squamous mucosa, no evidence of carcinoma.

[page 2 of 3]
(F) PHARYNGEAL MARGIN:

Squamous mucosa, no evidence of carcinoma.

(G) RIGHT HEMIMANDIBULAR AND TONGUE, COMPOSITE RESECTION:

INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA REPLACING THE POSTERIOR BODY OF THE RIGHT MANDIBLE AND GINGIVA WITH EXTENSION INTO THE LATERAL PORTION OF THE TONGUE, RESECTION MARGINS FREE OF TUMOR.

No lymphovascular or perineural invasion identified.

(H) TEETH:

Teeth, gross examination only.

Entire report and diagnosis completed by : [REDACTED]

Report released by [REDACTED]

COMMENT

The tumor measures 5.0 x 3.8 x 3.0 cm and extends to within 3.0 mm of the medial/inferior soft tissue margin. It obliterates the gingival-buccal sulcus as well as the floor of the mouth. Mandibular resection margins are grossly free of tumor and a supplemental report will be submitted following histological examination post decalcification.

GROSS DESCRIPTION

(A) SKIN FLAP RIGHT CHEEK (RIGHT CHECK MARGIN INKED) - A portion of black skin (2.8 x 1.4 cm with a depth of 0.8 cm).

Ink is present on one side. No distinct lesions are identified.

SECTION CODE: Inked portion submitted entirely for frozen section diagnosis as A en face. [REDACTED]

*FS/DX: SKIN, NO TUMOR PRESENT. [REDACTED]

(B) LEFT SUBMANDIBULAR NODE - Two lymph nodes, measuring 1.5 x 0.8 x 0.6 cm and 0.5 x 0.4 x 0.3 cm, respectively. Focally attached adipose tissue is present.

SECTION CODE: B1, larger lymph node, bisected; B2, smaller lymph node. [REDACTED]

(C) RIGHT NECK DISSECTION - A neck dissection specimen measuring 11.0 x 4.0 x 2.0 cm entirely. The specimen includes levels I, II and III. An unremarkable, tan-brown salivary gland is present in level I, measuring 3.5 x 3.0 x 2.0 cm. Multiple lymph nodes are present, measuring up to 1.3 cm in greatest dimension.

SECTION CODE: C1, salivary gland; C2-C8, level I lymph nodes as follows: C2, C3, 1 lymph node in 2 cassettes; C4-C7, 1 bisected lymph node each; C8, 3 lymph nodes; C9-C11, level II lymph nodes as follows: C9-C10, 1 bisected lymph node each; C11, multiple lymph nodes; C12-C14, level 3 lymph nodes as follows: C12, 1 bisected lymph node; C13, C14, multiple lymph nodes each. DS/beg/mgd

(D) MASSETER MARGIN - A portion of skeletal muscle (2.7 x 1.4 x 0.2 cm) with ink at one margin. No distinct lesions are identified grossly. Entirely submitted for frozen section inked side down (en face) in D1, D2. [REDACTED]

*FS/DX: SKELETAL MUSCLE, NO TUMOR PRESENT. [REDACTED]

[page 3 of 3]
[REDACTED]

(E) POSTERIOR BUCCAL MARGIN - A portion of mucosa covered soft tissue with ink on one end (2.0 x 0.4 x 0.3 cm). No distinct lesions are identified grossly. Entirely submitted for frozen section diagnosis, en face in E.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(F) PHARYNGEAL MARGIN - An irregular portion of tan-pink tissue which is not oriented (1.0 x 0.8 x 0.1 cm). Entirely submitted in F for frozen section diagnosis. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(G) RIGHT COMPOSITE RESECTION TONGUE AND MANDIBLE - A composite resection of right hemimandible including ramus and body with touch teeth, portion of lateral tongue and portion of adherent overlying skin of cheek. This specimen measures 12.0 x 8.0 x 6.0 cm overall.

A firm irregular tan-white tumor, 5.0 x 3.8 x 3.0 cm, replaces the posterior body of the mandible to the angle of the ramus as well as the soft tissues of the gingival buccal sulcus and right floor of mouth with extension to the lateral aspect of the tongue. Soft tissue, skin and bone marrow margins are all free of tumor. The medial-inferior soft tissue margin is the closest, 5.0 mm. The adherent/overlying skin has a central area that is puckered with underlying fibrosis that extends into the tumor.

INK CODE: Blue - medial; yellow - lateral; red - anterior; black - posterior.

SECTION CODE: G1-G4, tumor in area of replaced mandible; G5, G6, additional tumor; G7, G8, medial-inferior soft tissue margin, perpendicular; G9, medial skin margin, en face; G10-G12, tongue. Puckered skin adherent to tumor. Sections of tumor taken for research studies. [REDACTED]

(H) TEETH - Eight intact focally carious teeth measuring 6.0 x 5.0 x 1.3 cm in aggregate. Soft tissue is not present. Specimen submitted for gross only. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 08b721e3-7cc9-47a8-b20e-69530a2317fc (TCGA-CV-6954.8FC8CEC9-E1D7-497D-9223-C45D64F459AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).